Gene-level copy-number profile of tumor specimen ALCH-B37K-TTP1-A from ALCHEMIST case ALCH-B37K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.5 years (29,037 days).
Specimen ALCH-B37K-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file de40b07e-4a0b-40ce-a270-95b3a27e2ebb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B37K-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/616b8677-a00f-49dc-9d47-6ca217daf66c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 732; copy number 2: 57,487; copy number 3: 85; copy number 4: 15; copy number 5: 18; copy number 6: 1; copy number 10: 2; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:219,482,073–219,516,877, 5 genes (within-gene range 0–2): ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA.
- chr3:46,979,666–47,013,465, 2 genes (within-gene range 0–2): NBEAL2, NRADDP.
- chr5:177,600,132–177,610,330, 1 gene: B4GALT7.
- chr7:45,816,216–45,821,064, 3 genes: CICP20, AC096582.1, AC096582.2.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–2): MIR601.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:84,194,537–84,259,960, 4 genes: CDHR1, LRIT2, RGR, LRIT1.
- chr12:49,556,544–49,568,145, 1 gene (within-gene range 0–2): MCRS1.
- chr15:25,174,927–25,195,001, 12 genes (within-gene range 0–2): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14.
- chr17:63,507,056–63,548,977, 2 genes (within-gene range 0–2): ACE3P, KCNH6.
- chr19:4,356,637–4,358,448, 1 gene (within-gene range 0–2): AC007292.2.
- chr22:29,705,256–29,767,011, 5 genes: AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA.
- chr22:35,298,838–35,347,992, 4 genes: AL008635.1, TOM1, MIR3909, MIR6069.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:16,223,027–16,398,594, 18 genes, copy number 5 (within-gene range 2–5): AC136624.1, NOMO3, AC136624.3, AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3, PKD1P2, MIR6511A3, NPIPA7, AC136619.1.
- chr22:18,623,339–18,719,341, 4 genes, copy number 6–16: SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 732. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
